Somatic mutation profile of tumor specimen TCGA-EE-A3JA-06A (aliquot TCGA-EE-A3JA-06A-11D-A20D-08) from TCGA case TCGA-EE-A3JA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.6 years (17,372 days).
Specimen TCGA-EE-A3JA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5da5795-25da-4300-9e0a-f5938aeced1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3JA-10A (Blood Derived Normal), aliquot TCGA-EE-A3JA-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2eb523ba-a6c3-4c31-918e-f10ac9d5e2a1

The open-access MAF lists 1,252 somatic variants for this specimen: 790 protein-altering or splice-affecting, 420 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 721, Silent 420, Nonsense Mutation 33, Splice Region 20, Intron 16, RNA 14, Splice Site 8, 3'UTR 6, Frame Shift Del 4, 3'Flank 4, Translation Start Site 2, Frame Shift Ins 1.

Variants (750 of 1,252; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGB3 | c.1929-1G>A p.X643_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as rs750257554, COSV60688247; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 52/186 reads (28%) | catalogued as rs772994617, COSV54984261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NLRP7 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.043); catalogued as rs104895549, CM094501, COSV60173292; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 154/280 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMOC1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1365818420, CM138373, COSV62760517; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4696G>A p.E1566K (on ENST00000272895 / NM_173076.3; = p.E1248K on NM_015657.3) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs537765994, COSV55955863; called by muse, mutect2, varscan2
- ABCA13 | c.13988C>T p.S4663L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201250142; called by muse, mutect2, varscan2
- ABCB11 | c.3541A>T p.K1181* | Nonsense Mutation (SNP) | VAF 35/114 reads (31%) | catalogued as COSV55588968; called by muse, mutect2, varscan2
- ABL1 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV59329690; called by muse, mutect2, varscan2
- ACIN1 | c.3428G>A p.R1143Q | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.806); catalogued as rs771194310, COSV52975395; called by muse, mutect2, varscan2
- ACSL5 | c.1840G>A p.V614I (on ENST00000354273; = p.V670I on NM_016234.3) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61130122; called by muse, mutect2, varscan2
- ACSM1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54634883, COSV99533353; called by muse, mutect2, varscan2
- ACSM2A | c.481G>A p.D161N (on ENST00000219054; = p.D82N on NM_001308169.2) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs759558004, COSV54584023; called by muse, mutect2, varscan2
- ACTRT1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569354527, COSV64419031; called by muse, mutect2, varscan2
- ADAM18 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55845381; called by muse, mutect2, varscan2
- ADAM21 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs375714568, COSV50791466; called by muse, mutect2, varscan2
- ADAM28 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56099767; called by muse, mutect2, varscan2
- ADAM30 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65560887; called by muse, mutect2, varscan2
- ADAM7 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV51536912; called by muse, mutect2, varscan2
- ADAMTS18 | c.3595C>T p.P1199S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51404890; called by muse, mutect2, varscan2
- ADCY1 | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as COSV52033272; called by muse, mutect2, varscan2
- ADGRG4 | c.8671G>A p.D2891N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.511); catalogued as rs1244309826, COSV54954054; called by muse, mutect2, varscan2
- ADGRL3 | c.1276C>T p.P426S (on ENST00000506720 / NM_001322402.2; = p.P358S on NM_015236.6) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72267970; called by muse, mutect2, varscan2
- ADGRL3 | c.1694G>A p.S565N (on ENST00000506720 / NM_001322402.2; = p.S497N on NM_015236.6) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV72230252; called by muse, mutect2, varscan2
- ADGRV1 | c.8335C>T p.P2779S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV67983368; called by muse, mutect2
- ADH4 | c.626T>A p.V209E | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55500724; called by muse, mutect2, varscan2
- ADH7 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52920455; called by muse, mutect2, varscan2
- AFAP1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV61795000; called by muse, mutect2, varscan2
- AGBL1 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as rs746134714, COSV66855340; called by muse, mutect2, varscan2
- AHNAK | c.10664C>T p.P3555L | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57210866; called by muse, mutect2, varscan2
- AHNAK2 | c.1337T>G p.M446R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV60913214; called by muse, mutect2, varscan2
- AKNA | c.3953C>T p.S1318L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs946487891, COSV56336370; called by muse, mutect2, varscan2
- AL441992.2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV56913254; called by muse, mutect2, varscan2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- ALMS1 | c.4720G>A p.G1574R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752902461, COSV100042636, COSV100042904; called by muse, mutect2, varscan2
- ALMS1 | c.4721G>A p.G1574E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as COSV100042906; called by muse, mutect2, varscan2
- AMIGO1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63990346; called by muse, mutect2, varscan2
- AMY1A | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376235977, COSV100915794; called by muse, mutect2, varscan2
- AMY1A | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs1356493608, COSV100915778; called by mutect2, varscan2
- ANGPT4 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 39/73 reads (53%) | catalogued as COSV67921302; called by muse, mutect2, varscan2
- ANGPTL5 | c.654T>A p.D218E | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV57532665; called by muse, mutect2, varscan2
- ANKRD11 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV56359455; called by muse, mutect2, varscan2
- ANKRD24 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV53669577; called by muse, mutect2, varscan2
- ANO3 | c.334T>G p.Y112D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV56788660; called by muse, mutect2, varscan2
- ANO7 | c.1019G>A p.G340E (on ENST00000274979; = p.G286E on NM_001370694.2) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51470767; called by muse, mutect2
- ANTXR1 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV58012399; called by muse, mutect2, varscan2
- AP002512.3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1360393540, COSV54406256; called by muse, mutect2, varscan2
- APOB | c.8790A>C p.K2930N | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV51931997; called by muse, mutect2, varscan2
- APOD | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV58401843; called by muse, mutect2, varscan2
- AQP2 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs781478659, CM972978, COSV52229898; called by muse, mutect2
- ARAP1 | c.4276C>T p.R1426* (on ENST00000393609 / NM_001040118.2; = p.R1181* on NM_015242.4) | Nonsense Mutation (SNP) | VAF 46/86 reads (53%) | catalogued as rs759749576, COSV61990739; called by muse, mutect2, varscan2
- ARAP1 | c.3083C>T p.S1028F (on ENST00000393609 / NM_001040118.2; = p.S783F on NM_015242.4) | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1350237245, COSV61990747; called by muse, mutect2, varscan2
- ARHGAP29 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53110692; called by muse, mutect2, varscan2
- ARHGAP9 | c.1808G>A p.G603E (on ENST00000393797 / NM_001319850.2; = p.G584E on NM_032496.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57360766, COSV99954058; called by muse, mutect2, varscan2
- ARHGEF19 | c.1844T>A p.L615Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV54616193; called by muse, mutect2, varscan2
- ARHGEF25 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 62/175 reads (35%) | catalogued as COSV54085956; called by muse, mutect2, varscan2
- ARSF | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63839373; called by muse, mutect2, varscan2
- ASIC1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV57317556; called by muse, mutect2, varscan2
- ASPSCR1 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs765187547, COSV60728283; called by muse, mutect2, varscan2
- ASS1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as COSV61689023; called by muse, mutect2, varscan2
- ASTN1 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV62495342; called by muse, mutect2, varscan2
- ATF5 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV61311861; called by muse, mutect2, varscan2
- ATF7IP | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53769258; called by muse, mutect2, varscan2
- ATG4B | c.581C>A p.A194E | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV60350566, COSV60351153; called by muse, mutect2, varscan2
- ATG9A | c.445A>G p.K149E | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60132851; called by muse, mutect2, varscan2
- ATP10D | c.4169C>T p.S1390F | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs112565536, COSV56689990; called by muse, mutect2
- ATP13A1 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52284807; called by muse, mutect2, varscan2
- B3GAT1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); catalogued as rs866692838, COSV56996272; called by muse, mutect2, varscan2
- BAIAP3 | c.1173G>A p.R391= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV60979386; called by muse, mutect2, varscan2
- BCO1 | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV50729041; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BPIFB2 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064041; called by muse, mutect2, varscan2
- BPIFB6 | c.206T>A p.V69E | Missense Mutation (SNP) | VAF 122/234 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs567981759, COSV62754976; called by muse, mutect2, varscan2
- BPTF | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs145463211, COSV58835701; called by muse, mutect2, varscan2
- BRD7 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV67158616; called by muse, mutect2, varscan2
- BRD8 | c.1877C>G p.A626G (on ENST00000254900 / NM_139199.2; = p.A699G on NM_006696.4) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV50146954; called by muse, mutect2, varscan2
- BRINP1 | c.1979A>G p.Y660C | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56297549; called by muse, mutect2, varscan2
- BRINP3 | c.1647G>A p.M549I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.38); catalogued as rs1557963299, COSV66520672; called by muse, mutect2, varscan2
- BRPF3 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100325743, COSV60206911; called by muse, mutect2, varscan2
- BTBD11 | c.2196G>A p.M732I (on ENST00000280758 / NM_001018072.2; = p.M269I on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV55019873; called by muse, mutect2, varscan2
- BTBD8 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61546004; called by muse, mutect2, varscan2
- C10orf120 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs267602400, COSV100271561, COSV61491830; called by muse, mutect2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by muse, mutect2, varscan2
- C1QTNF9 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59656964, COSV59657345; called by muse, mutect2, varscan2
- C1orf198 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV64175160; called by muse, mutect2, varscan2
- C2orf16 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV68645874; called by muse, mutect2, varscan2
- C6orf118 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 175/232 reads (75%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV57814340; called by muse, mutect2, varscan2
- C7orf57 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62362446; called by muse, mutect2, varscan2
- CACNA1C | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59710283; called by muse, mutect2, varscan2
- CACNA1E | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as rs868416223, COSV62390434; called by muse, mutect2, varscan2
- CACNA1E | c.5801G>A p.G1934E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV62390443; called by muse, mutect2, varscan2
- CACNA1I | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760894270, COSV60800189; called by muse, mutect2, varscan2
- CACNA1I | c.5999C>T p.P2000L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60806004; called by muse, mutect2, varscan2
- CAMSAP2 | c.4364C>T p.P1455L (on ENST00000236925 / NM_001297707.2; = p.P1444L on NM_203459.3) | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52669426; called by muse, mutect2, varscan2
- CAND1 | c.1930T>A p.L644M | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV73389584; called by muse, mutect2, varscan2
- CAPN3 | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV58821381; called by muse, varscan2
- CASQ1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.618); catalogued as rs1403599353, COSV63623135; called by muse, mutect2, varscan2
- CASR | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 62/223 reads (28%) | catalogued as COSV56136645; called by muse, mutect2, varscan2
- CCDC148 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51758574; called by muse, mutect2, varscan2
- CCDC171 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs757205992, COSV52639800; called by muse, mutect2, varscan2
- CCDC180 | c.591C>T p.A197= | Splice Region (SNP) | VAF 12/44 reads (27%) | catalogued as COSV63829326; called by muse, mutect2, varscan2
- CCDC30 | c.1954C>T p.R652C (on ENST00000340612; = p.R609C on NM_001080850.3) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs141315303, COSV59605652; called by muse, mutect2, varscan2
- CCDC61 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV50516691; called by muse, mutect2, varscan2
- CDH10 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52577853; called by muse, mutect2, varscan2
- CDH16 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV55336192; called by muse, mutect2, varscan2
- CDH23 | c.2176G>A p.G726R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54930860; called by muse, mutect2
- CDH24 | c.1940C>T p.T647I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as COSV57460284; called by muse, mutect2, varscan2
- CDH7 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59884653; called by muse, mutect2, varscan2
- CDK12 | c.3917C>T p.S1306F (on ENST00000447079 / NM_016507.4; = p.S1297F on NM_015083.3) | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV71000276; called by muse, mutect2, varscan2
- CDK14 | c.937C>G p.L313V (on ENST00000380050 / NM_001287135.2; = p.L295V on NM_012395.3) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs537592613, COSV56031837; called by muse, mutect2, varscan2
- CEL | c.146C>T p.S49F (on ENST00000673714; = p.S46F on NM_001807.6) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.956); catalogued as COSV60826910; called by muse, mutect2, varscan2
- CEMIP | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs540926515, COSV54991164; called by muse, mutect2, varscan2
- CEP97 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV59123981; called by muse, mutect2, varscan2
- CER1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV66603115; called by muse, mutect2, varscan2
- CFAP46 | c.7633G>A p.E2545K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.158); catalogued as COSV54151209; called by muse, mutect2, varscan2
- CFAP47 | c.885G>A p.L295= | Splice Region (SNP) | VAF 6/10 reads (60%) | catalogued as COSV52883401; called by muse, mutect2, varscan2
- CFAP69 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV60185276; called by muse, mutect2
- CFTR | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs906983070, COSV50048120; called by muse, mutect2, varscan2
- CHRM2 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57764804, COSV57765460; called by mutect2, varscan2
- CHRNB1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53439447; called by muse, mutect2, varscan2
- CHRNB3 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51494500; called by muse, mutect2, varscan2
- CHST9 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779465790, COSV52434903, COSV52443413; called by muse, mutect2, varscan2
- CLEC17A | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60427336, COSV60427423; called by muse, mutect2, varscan2
- CLEC2B | c.238-1G>A p.X80_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV57309360; called by muse, mutect2, varscan2
- CLEC4G | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.277); catalogued as rs780612239, COSV61003141; called by muse, mutect2, varscan2
- CLIC2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs5940668, COSV58936260; called by muse, mutect2, varscan2
- CLPB | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV53629165; called by muse, varscan2
- CMTM2 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.844); catalogued as rs1346481564, COSV51748427; called by muse, mutect2, varscan2
- CNGB1 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs370932519; called by muse, mutect2, varscan2
- CNKSR2 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569272601, COSV54253998; called by muse, mutect2, varscan2
- CNOT1 | c.4751C>T p.P1584L | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55315241; called by muse, mutect2, varscan2
- CNST | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV63620274; called by muse, mutect2, varscan2
- CNTNAP2 | c.1910G>A p.W637* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV62147847; called by muse, mutect2, varscan2
- CNTNAP4 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571000371, COSV56664435; called by muse, mutect2, varscan2
- CNTROB | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 42/80 reads (53%) | catalogued as COSV100972612, COSV66607998; called by muse, mutect2, varscan2
- COBLL1 | c.2620C>T p.P874S (on ENST00000392717; = p.P836S on NM_014900.5) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52066501; called by muse, mutect2, varscan2
- COG8 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54742160; called by muse, mutect2, varscan2
- COL14A1 | c.2349G>A p.T783= | Splice Region (SNP) | VAF 20/36 reads (56%) | catalogued as rs1294108861, COSV52852244; called by muse, mutect2, varscan2
- COL1A1 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56804100; called by muse, varscan2
- COL21A1 | c.2455C>T p.H819Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55159705; called by muse, mutect2, varscan2
- COL21A1 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99779214; called by muse, mutect2
- COL22A1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 127/260 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57332908; called by muse, varscan2
- COL28A1 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68081706; called by muse, mutect2, varscan2
- COL2A1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.245); catalogued as COSV61528716; called by muse, mutect2, varscan2
- COL5A1 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV65667962; called by muse, mutect2, varscan2
- COL5A2 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs545487318, COSV66408878; called by muse, mutect2, varscan2
- COL8A1 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53732681; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV64958941; called by muse, mutect2, varscan2
- COMMD4 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs370320783; called by muse, mutect2, varscan2
- CORO1A | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532082; called by muse, mutect2, varscan2
- COX4I2 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as COSV65781772; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPN2 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV60470213; called by muse, mutect2, varscan2
- CRB1 | c.3455G>A p.G1152E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66329543, COSV66330761; called by muse, mutect2, varscan2
- CREB3L2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs778038461, COSV57794142; called by muse, mutect2, varscan2
- CSMD1 | c.10244C>T p.A3415V (on ENST00000520002; = p.A3414V on NM_033225.6) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59310346; called by muse, mutect2, varscan2
- CSMD1 | c.9806C>T p.T3269I (on ENST00000520002; = p.T3268I on NM_033225.6) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368288741, COSV59310388; called by muse, mutect2, varscan2
- CSMD1 | c.7508G>A p.G2503E (on ENST00000520002; = p.G2502E on NM_033225.6) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV59310410; called by muse, mutect2, varscan2
- CSMD2 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs754391035, COSV53902706, COSV99591642; called by muse, mutect2, varscan2
- CSMD2 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53902730; called by muse, mutect2, varscan2
- CSMD3 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.974); catalogued as COSV52156302; called by muse, mutect2, varscan2
- CTAGE6 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as rs1360175427, COSV101417860; called by mutect2, varscan2
- CTSF | c.926T>A p.F309Y | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV59748301; called by muse, mutect2, varscan2
- CUX2 | c.4262C>T p.S1421F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55629680; called by muse, mutect2, varscan2
- CWH43 | c.1863C>T p.I621= | Splice Region (SNP) | VAF 35/151 reads (23%) | catalogued as COSV56938041; called by muse, mutect2, varscan2
- CYP11B2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV100010983, COSV59994417; called by muse, mutect2, varscan2
- CYP21A2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs150804717; called by muse, mutect2, varscan2
- CYP4A11 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs531039219, COSV100152338, COSV60223067; called by muse, mutect2, varscan2
- CYP4A11 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV60223077; called by muse, mutect2, varscan2
- CYP4X1 | c.1260G>A p.W420* | Nonsense Mutation (SNP) | VAF 60/201 reads (30%) | catalogued as COSV64150455; called by muse, mutect2, varscan2
- DCTD | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs17849458, COSV63866858; called by muse, mutect2, varscan2
- DDA1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 87/257 reads (34%) | catalogued as COSV63289608; called by muse, mutect2, varscan2
- DDX27 | c.4G>A p.V2I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV65629499; called by muse, mutect2, varscan2
- DENND2C | c.2747G>A p.R916Q (on ENST00000393274 / NM_001256404.2; = p.R859Q on NM_198459.4) | Missense Mutation (SNP) | VAF 200/391 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs139442561; called by muse, mutect2, varscan2
- DHX8 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52252809; called by muse, mutect2, varscan2
- DIDO1 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as rs752548370, COSV56619675; called by muse, mutect2, varscan2
- DMD | c.6007G>A p.E2003K | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1319808956, COSV63748680; called by muse, mutect2, varscan2
- DNAAF1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57576963; called by muse, mutect2, varscan2
- DNAH10 | c.4240G>A p.E1414K (on ENST00000409039; = p.E1353K on NM_207437.3) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV68991875; called by muse, mutect2, varscan2
- DNAH12 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.9); catalogued as COSV60856543, COSV60857183; called by muse, mutect2, varscan2
- DNAH2 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 102/377 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV66718595; called by muse, mutect2, varscan2
- DNAH2 | c.11662G>A p.G3888R | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66718599; called by muse, mutect2, varscan2
- DNAH3 | c.8095G>A p.E2699K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54509447, COSV54516276; called by muse, mutect2, varscan2
- DNAH5 | c.12905T>C p.I4302T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54218661; called by muse, varscan2
- DNAH5 | c.7268T>A p.I2423N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV54218682; called by muse, mutect2, varscan2
- DNAH5 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54217167; called by muse, mutect2, varscan2
- DNAH8 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1247188381, COSV59438883; called by muse, mutect2, varscan2
- DNAH8 | c.7639G>A p.E2547K | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59438908; called by muse, mutect2, varscan2
- DNAH9 | c.6314G>A p.R2105Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761304608, COSV52333260; called by muse, mutect2
- DNAJC1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1172518642, COSV65410402; called by muse, mutect2, varscan2
- DNAJC16 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV65435789; called by muse, mutect2, varscan2
- DNMBP | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | catalogued as COSV60623848; called by muse, mutect2, varscan2
- DOK3 | c.474G>A p.V158= | Splice Region (SNP) | VAF 13/46 reads (28%) | catalogued as COSV57251844; called by muse, mutect2, varscan2
- DPP4 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62106215; called by muse, mutect2, varscan2
- DPPA2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs922189877, COSV72118023; called by muse, mutect2, varscan2
- DPPA4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509998; called by muse, mutect2, varscan2
- DPYD | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60076147; called by muse, mutect2, varscan2
- DRD2 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.921); catalogued as COSV60754342; called by muse, mutect2, varscan2
- DSC3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV64572640; called by muse, mutect2, varscan2
- DSCAM | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68021687; called by muse, mutect2, varscan2
- DSG2 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV55198430, COSV99853037; called by muse, mutect2, varscan2
- DSG4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57390641; called by muse, mutect2, varscan2
- DSG4 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1244455121, COSV57389442; called by muse, mutect2, varscan2
- DSP | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as COSV65790764; called by muse, mutect2, varscan2
- DUOX2 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101199804; called by mutect2, varscan2
- DYNAP | c.173C>T p.S58F (on ENST00000321600; = p.S32F on NM_173629.3) | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV58666263; called by muse, mutect2, varscan2
- EDRF1 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs149421957, COSV100523886; called by muse, mutect2, varscan2
- EGFL6 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 72/95 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100789876, COSV63633565; called by muse, mutect2, varscan2
- EGFLAM | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV59298935; called by muse, mutect2, varscan2
- EGFLAM | c.2911G>A p.E971K (on ENST00000354891 / NM_001205301.2; = p.E963K on NM_152403.4) | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV59294308; called by muse, mutect2, varscan2
- EHBP1L1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100499942; called by muse, mutect2, varscan2
- ELAC2 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 180/326 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV52392944; called by muse, mutect2, varscan2
- ELFN2 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427255066, COSV68744360; called by muse, mutect2, varscan2
- ELMO3 | c.919C>T p.L307F (on ENST00000652269; = p.L254F on NM_024712.5) | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV62606334; called by muse, mutect2, varscan2
- EML5 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.279); catalogued as rs754576737, COSV61344454; called by muse, mutect2, varscan2
- ENO2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as rs940367848, COSV57544627, COSV99980465; called by muse, mutect2, varscan2
- EPB41L1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52436790; called by muse, mutect2, varscan2
- EPHB6 | c.1498C>G p.R500G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV63891363; called by muse, mutect2, varscan2
- ERBB4 | c.2874G>A p.M958I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV61480455; called by muse, mutect2, varscan2
- ERBB4 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV61480464; called by muse, mutect2, varscan2
- ERF | c.96T>G p.F32L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55895565; called by muse, mutect2, varscan2
- EVPL | c.4607G>A p.R1536Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs747340763, COSV56909794; called by muse, mutect2, varscan2
- FAM47A | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV100649967; called by muse, mutect2, varscan2
- FAM71B | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 84/141 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV57228586; called by muse, mutect2, varscan2
- FANCD2 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV55036352; called by muse, mutect2, varscan2
- FANCI | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV55525924; called by muse, mutect2, varscan2
- FARSA | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs755136781, COSV53366338; called by muse, mutect2, varscan2
- FAT4 | c.9398G>A p.G3133E | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58680348; called by muse, mutect2, varscan2
- FBN3 | c.5726C>T p.S1909F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54458510; called by muse, mutect2, varscan2
- FER1L6 | c.3956G>A p.G1319E | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67549400; called by muse, mutect2, varscan2
- FGA | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs754425204, COSV100120496, COSV57395375; called by muse, mutect2, varscan2
- FGD5 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.36); catalogued as COSV53240922; called by muse, mutect2, varscan2
- FGF2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV52649399; called by muse, mutect2, varscan2
- FKBP3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV53531869; called by muse, mutect2, varscan2
- FLAD1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as COSV52696160; called by muse, mutect2, varscan2
- FLG2 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 250/483 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1426438273, COSV66166507; called by muse, mutect2, varscan2
- FLG2 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV66167986; called by muse, mutect2, varscan2
- FLT1 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 158/295 reads (54%) | catalogued as COSV56725368; called by muse, mutect2, varscan2
- FOXH1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs769851942, COSV56760763; called by muse, mutect2, varscan2
- FRG2 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs2037950, COSV66459875; called by muse, mutect2, varscan2
- FSHB | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54221267; called by muse, mutect2, varscan2
- FTMT | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs766232627, COSV58420197; called by muse, mutect2, varscan2
- FUT4 | c.1291T>A p.L431M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV62469216; called by muse, mutect2, varscan2
- FYB1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV60944861; called by muse, mutect2, varscan2
- GAA | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100163345; called by muse, mutect2, varscan2
- GABRB3 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV54655923, COSV54662434; called by muse, mutect2, varscan2
- GAD1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432510263, COSV64025488; called by muse, mutect2, varscan2
- GALNT1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV52451870; called by muse, mutect2, varscan2
- GALNT17 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61153803; called by muse, mutect2, varscan2
- GAP43 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV59343626; called by muse, mutect2, varscan2
- GAS2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV53406790; called by muse, mutect2, varscan2
- GCN1 | c.5154G>A p.Q1718= | Splice Region (SNP) | VAF 18/63 reads (29%) | catalogued as COSV56106599; called by muse, mutect2, varscan2
- GDF10 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs782431049; called by muse, mutect2, varscan2
- GET4 | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as rs934907700, COSV99763177; called by muse, mutect2, varscan2
- GFRA3 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs749208735, COSV51228178; called by muse, mutect2, varscan2
- GIMAP7 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV57959180; called by muse, mutect2, varscan2
- GJB6 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV53832368; called by muse, mutect2, varscan2
- GLB1L2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 106/157 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56995292; called by muse, varscan2
- GLYATL1 | c.682G>A p.E228K (on ENST00000317391 / NM_001354699.1; = p.E259K on NM_080661.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55608517; called by muse, mutect2, varscan2
- GOLGB1 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61464690; called by muse, mutect2, varscan2
- GPR89A | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782758265, COSV100572479; called by muse, mutect2, varscan2
- GPRIN2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs868993240, COSV100966428, COSV65400839; called by muse, mutect2, varscan2
- GRB10 | c.1508C>T p.S503F (on ENST00000398812; = p.S457F on NM_001001549.3) | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1246214780, COSV60009606; called by muse, mutect2, varscan2
- GRIK3 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.073); catalogued as COSV66138433; called by muse, mutect2, varscan2
- GRIN2A | c.3395C>T p.P1132L | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100409852, COSV58020198; called by muse, mutect2, varscan2
- GRIN3A | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868638738, COSV62451702; called by muse, mutect2, varscan2
- GRM1 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51125065, COSV51130704; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56085961; called by muse, mutect2, varscan2
- GTPBP4 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141121079, COSV62550643; called by muse, mutect2, varscan2
- HASPIN | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as rs770982021, COSV53992848; called by muse, mutect2, varscan2
- HCN1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV57502869; called by muse, mutect2, varscan2
- HDAC11 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV55472938; called by muse, mutect2, varscan2
- HEATR6 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV51744958; called by muse, mutect2, varscan2
- HIVEP3 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56013735; called by muse, mutect2, varscan2
- HJURP | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV64978700; called by muse, mutect2, varscan2
- HK2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51872842; called by muse, mutect2, varscan2
- HLA-DPB1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1182203666, COSV69603076; called by muse, mutect2, varscan2
- HMG20A | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.775); catalogued as COSV60312180; called by muse, mutect2, varscan2
- HMGCS2 | c.1422G>A p.V474= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as COSV65567731; called by muse, mutect2, varscan2
- HNRNPK | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV61089257; called by muse, mutect2
- HNRNPK | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV61089262; called by muse, mutect2
- HPN | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52883166; called by muse, mutect2, varscan2
- HS3ST4 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58811055; called by muse, mutect2, varscan2
- HSF2 | c.1046A>T p.N349I | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV63773804; called by muse, mutect2, varscan2
- HYDIN | c.12109C>T p.H4037Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV66638475; called by muse, mutect2, varscan2
- IGHV2-70 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs370286145; called by muse, mutect2, varscan2
- IGKV1-27 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs772037997; called by muse, mutect2, varscan2
- IGKV1D-42 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs761056614; called by muse, mutect2, varscan2
- IGSF9B | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs1004437425, COSV58064431; called by muse, mutect2, varscan2
- IL1RL1 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.121); catalogued as COSV52114319, COSV52120872; called by muse, mutect2, varscan2
- IL31RA | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV61693817; called by muse, mutect2, varscan2
- IL31RA | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs763337032, COSV61692662; called by muse, mutect2, varscan2
- IL33 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs1229357818, COSV67343003; called by muse, mutect2, varscan2
- IQCF1 | c.109-1G>A p.X37_splice | Splice Site (SNP) | VAF 36/139 reads (26%) | catalogued as rs1255990910, COSV58823325; called by muse, mutect2, varscan2
- IQGAP2 | c.3248C>T p.S1083L | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as rs768262402, COSV57171906; called by muse, mutect2, varscan2
- IRAG2 | c.4075C>T p.L1359F (on ENST00000636465; = p.L404F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57231607; called by muse, mutect2, varscan2
- IRAK1 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 80/106 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57653215; called by muse, mutect2, varscan2
- IRAK2 | c.1275G>A p.K425= | Splice Region (SNP) | VAF 16/79 reads (20%) | catalogued as rs367807487; called by muse, mutect2, varscan2
- IRF8 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1377715288, COSV51897656; called by muse, mutect2, varscan2
- ITGA2 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56858731; called by muse, mutect2, varscan2
- JCAD | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV64759106; called by muse, mutect2, varscan2
- KATNIP | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55178623; called by muse, mutect2, varscan2
- KCNQ1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs372583676; called by muse, mutect2, varscan2
- KCNT1 | c.2954C>T p.S985L (on ENST00000488444; = p.S1004L on NM_020822.3) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1564390954, COSV53699774; called by muse, mutect2, varscan2
- KCNT2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54074924; called by muse, mutect2, varscan2
- KCNU1 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV67754924; called by muse, mutect2, varscan2
- KCTD14 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62001317; called by muse, mutect2, varscan2
- KCTD16 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV72578280; called by muse, mutect2, varscan2
- KEL | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1279058708, COSV62333294; called by muse, mutect2, varscan2
- KIAA0319 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770007032, COSV65497736; called by muse, mutect2, varscan2
- KIAA1143 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56088848; called by muse, varscan2
- KIAA1217 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56815455; called by muse, mutect2, varscan2
- KIF18A | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs912384116, COSV54182497; called by muse, mutect2, varscan2
- KIR2DL1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52408846; called by muse, mutect2, varscan2
- KIR3DL3 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV99400011; called by muse, mutect2, varscan2
- KLHDC8A | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65678641; called by muse, mutect2, varscan2
- KLHL31 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.914); catalogued as rs756981198, COSV63881383; called by muse, mutect2, varscan2
- KLHL6 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1460869404, COSV58064460; called by muse, mutect2, varscan2
- KLK5 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.218); catalogued as rs748294116, COSV60449437; called by muse, mutect2, varscan2
- KMT2A | c.8741C>T p.S2914F | Missense Mutation (SNP) | VAF 124/171 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); catalogued as COSV63284683; called by muse, mutect2, varscan2
- KMT2C | c.11363C>T p.S3788F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs770450253, COSV51429850; called by muse, mutect2, varscan2
- KNDC1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58835261; called by muse, mutect2, varscan2
- KRT16 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CM994216, BM1458522, COSV56967667; called by muse, mutect2, varscan2
- KRT20 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51424591; called by muse, mutect2, varscan2
- KRT6C | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99359896; called by muse, mutect2, varscan2
- KRT74 | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.107); catalogued as COSV59771073; called by muse, mutect2, varscan2
- KRTAP10-6 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100554344; called by muse, mutect2, varscan2
- KRTAP5-10 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as COSV64794186; called by muse, mutect2, varscan2
- KRTAP8-1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs950288305, COSV61597894; called by muse, mutect2, varscan2
- LAMB2 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs1207488077, COSV59732689; called by muse, mutect2, varscan2
- LCE1B | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 111/227 reads (49%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.608); catalogued as COSV63980261; called by muse, mutect2, varscan2
- LCK | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs200647118, COSV60739755; called by muse, mutect2, varscan2
- LCK | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV60739779; called by muse, mutect2, varscan2
- LETM2 | c.1135C>T p.P379S (on ENST00000379957 / NM_001286819.2; = p.P284S on NM_144652.3) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs1019742176, COSV52685949; called by muse, mutect2, varscan2
- LGSN | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV65726877; called by muse, mutect2, varscan2
- LIFR | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54688495; called by muse, mutect2
- LIFR | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.588); catalogued as COSV54688509; called by muse, mutect2, varscan2
- LIPI | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1264687131, COSV60710416; called by muse, mutect2, varscan2
- LPIN3 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1355113414, COSV60035788; called by muse, mutect2, varscan2
- LRCH4 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs781177002, COSV59643002; called by muse, mutect2, varscan2
- LRG1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV56703341; called by muse, mutect2, varscan2
- LRP2 | c.7624C>T p.R2542C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55549686, COSV99786393; called by muse, mutect2, varscan2
- LRP2 | c.6814C>T p.R2272C | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs368840374, COSV55549698, COSV55562869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC43 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs942534186, COSV60289174; called by muse, mutect2, varscan2
- LRRN1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs550318532, COSV60013335; called by muse, mutect2, varscan2
- LRRTM3 | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.221); catalogued as COSV63664249; called by muse, mutect2, varscan2
- LTF | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51607248; called by muse, mutect2, varscan2
- LUZP2 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV61201754; called by muse, mutect2, varscan2
- LY75 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104472, COSV55111771; called by muse, mutect2, varscan2
- MACC1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV60542080; called by muse, mutect2, varscan2
- MACF1 | c.9395C>T p.S3132F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV57117590; called by muse, mutect2, varscan2
- MAD2L1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56636813; called by muse, mutect2, varscan2
- MADD | c.4795C>T p.P1599S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs865887718, COSV57026052; called by muse, mutect2, varscan2
- MAGEB10 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs1438258148, COSV63310963, COSV63312330; called by muse, mutect2
- MAGEB6 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.786); catalogued as COSV66872119, COSV66873247; called by muse, mutect2, varscan2
- MAGEC1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53571393; called by muse, mutect2, varscan2
- MAGEC1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs774034395, COSV53571401; called by muse, mutect2, varscan2
- MAK | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as COSV57565018; called by muse, mutect2, varscan2
- MAP3K19 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV59636805; called by muse, mutect2, varscan2
- MAP3K9 | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67120010, COSV67120953; called by muse, mutect2, varscan2
- MAP4K2 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV53642330; called by muse, mutect2, varscan2
- MAP7 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1322634794, COSV63418972; called by muse, mutect2, varscan2
- MAPKBP1 | c.1238C>T p.S413F (on ENST00000456763 / NM_001128608.2; = p.S407F on NM_014994.3) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267604190, COSV52960314; called by muse, mutect2, varscan2
- MARCO | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100503603, COSV59052677; called by muse, mutect2, varscan2
- MCAT | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 74/184 reads (40%) | catalogued as COSV51792355; called by muse, mutect2, varscan2
- MCMDC2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV58035414; called by muse, mutect2, varscan2
- MDGA1 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.138); catalogued as COSV51794772; called by muse, mutect2, varscan2
- MEFV | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1189709287, COSV54820788; called by muse, mutect2
- MGAM | c.3380C>T p.P1127L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV72074298; called by muse, mutect2, varscan2
- MGAT5 | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56095778; called by muse, mutect2, varscan2
- MKRN3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV58808964; called by muse, mutect2, varscan2
- MKX | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs904398076, COSV65391974; called by muse, mutect2, varscan2
- MMP26 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1203432149, COSV56171991; called by muse, mutect2, varscan2
- MOGAT1 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261812774, COSV71479867; called by muse, mutect2, varscan2
- MORC1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51718133; called by muse, mutect2, varscan2
- MPL | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV100991634; called by muse, mutect2, varscan2
- MPL | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV100991635; called by muse, mutect2, varscan2
- MRM2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54247956; called by muse, varscan2
- MROH2B | c.4636G>A p.E1546K | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs376683021; called by muse, mutect2, varscan2
- MROH2B | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV68181475; called by muse, mutect2, varscan2
- MTSS1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1278997450, COSV61496452; called by muse, mutect2
- MUC16 | c.42065G>T p.G14022V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66691271; called by muse, mutect2, varscan2
- MUC16 | c.37075C>T p.P12359S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as rs562224893, COSV67460143; called by muse, mutect2, varscan2
- MUC16 | c.35552C>T p.S11851F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV101200010, COSV67460149; called by muse, mutect2, varscan2
- MUC16 | c.10711G>A p.E3571K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs564503992, COSV67453406, COSV67460165; called by muse, mutect2, varscan2
- MUC16 | c.9530G>A p.G3177E | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.111); catalogued as rs267605805, COSV67445711, COSV67462454; called by muse, mutect2, varscan2
- MUC16 | c.7951C>T p.P2651S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67460180; called by muse, mutect2, varscan2
- MUC17 | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV60285984; called by muse, mutect2, varscan2
- MUC17 | c.6425C>T p.S2142F | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV60285988; called by muse, mutect2, varscan2
- MUC4 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV100638825, COSV62144301; called by muse, mutect2, varscan2
- MXRA5 | c.7465C>T p.P2489S | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746921444, COSV54232019; called by muse, mutect2, varscan2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MYH2 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs745357669, COSV55431560; called by muse, mutect2, varscan2
- MYH7 | c.5419G>A p.G1807S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745729408, COSV62518342; called by muse, mutect2, varscan2
- MYLK | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750437332, COSV60606159; called by muse, varscan2
- MYLK | c.154T>A p.F52I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV60608667; called by muse, mutect2, varscan2
- MYO15A | c.8830C>T p.P2944S | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52755287; called by muse, mutect2, varscan2
- MYO18B | c.4601A>T p.K1534M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59131493; called by muse, mutect2, varscan2
- MYO1C | c.446C>T p.A149V (on ENST00000648651 / NM_001080779.2; = p.A114V on NM_033375.5) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1169572803, COSV62998997; called by muse, mutect2, varscan2
- MYO6 | c.3550C>T p.P1184S (on ENST00000369981; = p.P1174S on NM_004999.4) | Missense Mutation (SNP) | VAF 94/136 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs950765065, COSV100889377; called by muse, mutect2, varscan2
- MYO6 | c.3551C>T p.P1184L (on ENST00000369981; = p.P1174L on NM_004999.4) | Missense Mutation (SNP) | VAF 96/137 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100889378; called by muse, mutect2, varscan2
- MYSM1 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV68977336; called by muse, mutect2, varscan2
- MYT1L | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757649588, COSV67717585; called by muse, mutect2, varscan2
- NAALAD2 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.984); catalogued as rs150474449; called by muse, mutect2, varscan2
- NAGS | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV52814352; called by muse, mutect2, varscan2
- NAP1L2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 66/86 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as COSV65172393; called by muse, mutect2, varscan2
- NAPSA | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53797228; called by muse, mutect2, varscan2
- NAPSA | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.968); catalogued as rs1158441785, COSV53796677; called by muse, mutect2, varscan2
- NBEAL2 | c.4535C>T p.P1512L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52756607; called by muse, mutect2, varscan2
- NCOA3 | c.2075G>A p.G692E | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59067643; called by muse, mutect2, varscan2
- NEBL | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767254277, COSV65839103; called by muse, mutect2, varscan2
- NEIL3 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs767326288, COSV52809867; called by muse, mutect2, varscan2
- NGEF | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV99889702; called by muse, mutect2, varscan2
- NGEF | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs923626488, COSV50918672; called by muse, mutect2, varscan2
- NKD1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV51690712; called by muse, mutect2, varscan2
- NLRP8 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV99405531; called by muse, mutect2, varscan2
- NOTCH3 | c.5053G>A p.D1685N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as COSV54632372; called by muse, mutect2, varscan2
- NPHS1 | c.3023G>A p.R1008K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.506); catalogued as COSV62287408; called by muse, mutect2, varscan2
- NPR1 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64140935; called by muse, mutect2, varscan2
- NPY2R | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 94/178 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs772110714, COSV61527869; called by muse, mutect2
- NPY5R | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs866941603, COSV58451682; called by muse, mutect2, varscan2
- NR2E3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV58908073; called by muse, mutect2, varscan2
- NR5A2 | c.322G>A p.G108R (on ENST00000367362 / NM_205860.3; = p.G62R on NM_003822.5) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52648722; called by muse, mutect2, varscan2
- NRIP1 | c.3002C>T p.S1001L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV59656768; called by muse, mutect2
- NSUN7 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs749806099, COSV99923456; called by muse, varscan2
- NSUN7 | c.1527G>A p.R509= | Splice Region (SNP) | VAF 53/110 reads (48%) | catalogued as COSV99923457; called by muse, varscan2
- NTRK1 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374918502; called by muse, mutect2, varscan2
- NUP210 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV54405186; called by muse, mutect2, varscan2
- NUP210 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54405192; called by muse, mutect2, varscan2
- NWD1 | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs749002654, COSV60354608; called by muse, mutect2, varscan2
- OBSCN | c.18394G>A p.E6132K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs766779029, COSV52764080; called by muse, mutect2, varscan2
- OPALIN | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.75); catalogued as rs1441365084, COSV64520488; called by muse, mutect2, varscan2
- OPN5 | c.170T>A p.M57K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV55245085; called by muse, mutect2, varscan2
- OR10C1 | c.784C>T p.R262C (on ENST00000622521; = p.R260C on NM_013941.3) | Missense Mutation (SNP) | VAF 212/547 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1358295170, COSV65822163, COSV65823505; called by muse, mutect2, varscan2
- OR10J1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 119/216 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV71128685; called by muse, mutect2, varscan2
- OR10K2 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV59220448; called by muse, mutect2, varscan2
- OR11G2 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.374); catalogued as COSV62132111; called by muse, mutect2, varscan2
- OR11G2 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs756257494, COSV62132118; called by muse, mutect2, varscan2
- OR13G1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1360103231, COSV62943929, COSV62944575; called by muse, mutect2, varscan2
- OR1G1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV61030055; called by muse, mutect2, varscan2
- OR1L8 | c.421C>G p.H141D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV59186233, COSV59186650; called by muse, mutect2, varscan2
- OR2AK2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs200166151, COSV63551806; called by muse, mutect2, varscan2
- OR2C3 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV63574855; called by muse, mutect2
- OR2M2 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100677270, COSV62898165; called by muse, mutect2, varscan2
- OR2T5 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323610842, COSV63540571; called by muse, mutect2, varscan2
- OR4A15 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as rs371095350; called by muse, mutect2, varscan2
- OR4L1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59849529, COSV59851155; called by muse, mutect2, varscan2
- OR51V1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs777451547, COSV58314889; called by muse, mutect2, varscan2
- OR5D13 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777852254, COSV100686654, COSV62332645; called by muse, mutect2, varscan2
- OR5H15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV62947758; called by muse, mutect2, varscan2
- OR5L1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 179/352 reads (51%) | catalogued as COSV61733581; called by muse, mutect2, varscan2
- OR6C68 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV65563120, COSV65564181; called by muse, mutect2, varscan2
- OR6N1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV58648016; called by muse, mutect2, varscan2
- OR7C2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV50180252; called by muse, mutect2, varscan2
- OR8D1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs773542872, COSV63442046; called by muse, mutect2, varscan2
- OR8J3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV56880208, COSV56883621; called by muse, mutect2, varscan2
- OSBPL5 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs758721623, COSV55141110; called by muse, mutect2
- OSBPL8 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866552441, COSV53878087, COSV53880397; called by muse, mutect2, varscan2
- P2RX3 | c.328-1G>A p.X110_splice | Splice Site (SNP) | VAF 10/12 reads (83%) | catalogued as COSV54442178; called by muse, mutect2
- P2RX3 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54442186; called by muse, mutect2, varscan2
- P3H3 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51832497; called by muse, mutect2, varscan2
- PAPPA | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60289183; called by muse, mutect2, varscan2
- PAPPA | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.489); catalogued as rs761344612, COSV60279974, COSV60281234; called by muse, mutect2, varscan2
- PAPPA2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 61/108 reads (56%) | catalogued as rs557625059, COSV100867139, COSV62772170; called by muse, mutect2, varscan2
- PAPPA2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV62776555; called by muse, mutect2, varscan2
- PAPPA2 | c.4079C>T p.S1360F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62795455; called by muse, varscan2
- PAPPA2 | c.4381C>T p.P1461S | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62795467; called by muse, mutect2, varscan2
- PBLD | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV53265330, COSV53265705; called by muse, mutect2, varscan2
- PCDH15 | c.4639G>A p.G1547S (on ENST00000644397 / NM_001354429.2; = p.G1496S on NM_001142769.3) | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV64688259; called by muse, mutect2, varscan2
- PCDH18 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs868367262, COSV61267661; called by muse, mutect2, varscan2
- PCDH18 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); catalogued as COSV100787328, COSV61267675; called by muse, mutect2, varscan2
- PCDHA6 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as COSV65342295; called by muse, mutect2, varscan2
- PCDHAC1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 115/207 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs762916391, COSV53835909; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, mutect2, varscan2
- PCDHB4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs782603101, COSV52021666; called by muse, mutect2, varscan2
- PCDHB7 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.021); catalogued as rs782535815, COSV50762150, COSV50823479; called by muse, mutect2, varscan2
- PCDHGA1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs866208625, COSV65295357; called by muse, mutect2, varscan2
- PCDHGA8 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV53930746; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCED1B | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs141120293, COSV71394900; called by muse, mutect2, varscan2
- PCSK1 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60734760; called by muse, mutect2, varscan2
- PCSK9 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs758109994, COSV56161751; called by muse, mutect2, varscan2
- PDCL2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.668); catalogued as COSV55260117; called by muse, mutect2, varscan2
- PDE1A | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1398006488, COSV59520789; called by muse, mutect2, varscan2
- PDE1C | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58510814; called by muse, mutect2, varscan2
- PDE2A | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV57805386; called by muse, mutect2, varscan2
- PDE3A | c.2323C>T p.L775F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as COSV62971299; called by muse, mutect2, varscan2
- PDE6A | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as rs765835448, COSV54926556; called by muse, mutect2, varscan2
- PDE6B | c.2196C>T p.V732= | Splice Region (SNP) | VAF 19/54 reads (35%) | catalogued as rs370954725; called by muse, mutect2, varscan2
- PDE6C | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.193); catalogued as rs772889663, COSV65115534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDGFB | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs770065392, COSV58646543; called by muse, mutect2, varscan2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by muse, mutect2, varscan2
- PDZD8 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57824886; called by muse, mutect2, varscan2
- PDZK1 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV58259002; called by muse, mutect2, varscan2
- PENK | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1377419372, COSV59240662, COSV59242614; called by muse, mutect2, varscan2
- PFKL | c.2193C>T p.F731= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs753348614, COSV57394266, COSV57394492; called by muse, mutect2, varscan2
- PGS1 | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53144657; called by muse, mutect2, varscan2
- PHF1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs751239683, COSV65702668; called by muse, mutect2, varscan2
- PHF24 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV54273989; called by muse, mutect2, varscan2
- PHF3 | c.4202C>T p.S1401F | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50316655, COSV50325670, COSV50331070; called by muse, mutect2, varscan2
- PHKA1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59804835; called by muse, mutect2, varscan2
- PHKB | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1432639799, COSV54519342; called by muse, mutect2, varscan2
- PHLPP1 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99408587; called by muse, mutect2, varscan2
- PHLPP1 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99408594; called by muse, mutect2, varscan2
- PHRF1 | c.3463C>T p.P1155S (on ENST00000264555 / NM_001286581.2; = p.P1154S on NM_020901.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV52754560; called by muse, mutect2
- PIAS1 | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV51031274; called by muse, mutect2, varscan2
- PIGQ | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV50312928; called by muse, mutect2, varscan2
- PKHD1 | c.9982C>T p.P3328S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61870958; called by muse, mutect2, varscan2
- PKHD1L1 | c.7121C>T p.P2374L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV101006453; called by muse, varscan2
- PLA2G4E | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV68149836; called by muse, mutect2, varscan2
- PLCB4 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53799004; called by muse, mutect2, varscan2
- PLCL2 | c.3186G>A p.W1062* (on ENST00000615277 / NM_001144382.2; = p.W936* on NM_015184.5) | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as COSV67621670; called by muse, mutect2, varscan2
- PLCXD3 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs559527240, COSV60607794; called by muse, varscan2
- PLCXD3 | c.839T>A p.V280D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV60607400; called by muse, varscan2
- PLG | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV51982153; called by muse, mutect2, varscan2
- PNPO | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56666328; called by muse, mutect2, varscan2
- PODXL | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as rs377478180; called by muse, mutect2, varscan2
- POU2F2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60761674; called by muse, mutect2, varscan2
- PPP2R2C | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58671864; called by muse, mutect2, varscan2
- PRAMEF1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV60006682; called by muse, mutect2, varscan2
- PRKACG | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs867924490, COSV55245899; called by muse, mutect2, varscan2
- PRSS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61192374; called by muse, varscan2
- PRSS1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV61192382; called by muse, varscan2
- PRSS1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as CM011002, COSV61190935; called by muse, mutect2, varscan2
- PRUNE2 | c.5657C>T p.P1886L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs773601483, COSV65040580; called by muse, mutect2, varscan2
- PSD3 | c.1985G>A p.R662K | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54070001, COSV54072718; called by muse, mutect2, varscan2
- PSG11 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV60454747; called by muse, mutect2, varscan2
- PSG4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs1219285842, COSV54935111; called by muse, mutect2, varscan2
- PSG7 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68444549; called by muse, mutect2, varscan2
- PSG9 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454377680, COSV52484573; called by muse, varscan2
- PSTPIP2 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs769993373, COSV68444065; called by muse, mutect2, varscan2
- PTGER3 | c.1081G>A p.E361K (on ENST00000628037 / NM_198717.2; = p.E370K on NM_198716.2) | Missense Mutation (SNP) | VAF 149/281 reads (53%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs771757558, COSV63388000; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.57G>A p.M19I (on ENST00000421990 / NM_001136042.2; = p.M1? on NM_025267.3) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100799212, COSV64182475; called by muse, mutect2, varscan2
- PTN | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61964765; called by muse, mutect2, varscan2
- PTPN13 | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs1322974998, COSV57405926; called by muse, mutect2, varscan2
- PTPN22 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV63084826; called by muse, mutect2, varscan2
- PTPN5 | c.1658G>A p.S553N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100079981; called by muse, mutect2, varscan2
- PTPRC | c.101-1G>A p.X34_splice | Splice Site (SNP) | VAF 21/127 reads (17%) | catalogued as rs766200564, COSV61409733; called by muse, mutect2, varscan2
- PTPRT | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.354); catalogued as rs1259827929, COSV61975235; called by muse, mutect2, varscan2
- RAD9B | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV62826023; called by muse, mutect2, varscan2
- RAG1 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55024790; called by muse, mutect2, varscan2
- RAI1 | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs777498429, COSV55391978; called by muse, mutect2, varscan2
- RANBP3L | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV56954444, COSV56955268; called by muse, mutect2, varscan2
- RAPGEF3 | c.2437C>T p.P813S (on ENST00000389212; = p.P771S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50201909; called by muse, mutect2, varscan2
- RASAL1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs780843452, COSV55655310; called by muse, mutect2, varscan2
- RBM45 | c.740C>T p.S247F (on ENST00000616198 / NM_001365579.1; = p.S245F on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1206705925, COSV53721084; called by muse, mutect2, varscan2
- RBMS3 | c.1202C>T p.P401L (on ENST00000383767 / NM_001003793.3; = p.P385L on NM_014483.3) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV56140478; called by muse, mutect2, varscan2
- RCAN2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.533); catalogued as COSV57815928; called by muse, mutect2, varscan2
- RGS12 | c.4052C>T p.P1351L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763063840, COSV58750796; called by muse, mutect2, varscan2
- RIF1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV54615662; called by muse, mutect2, varscan2
- RIMS2 | c.4338G>A p.M1446I (on ENST00000666250 / NM_001348490.2; = p.M1017I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51672707; called by muse, mutect2, varscan2
- RIPK3 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53475018; called by muse, mutect2, varscan2
- RNF128 | c.620C>T p.S207L (on ENST00000255499 / NM_194463.2; = p.S181L on NM_024539.3) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.98); catalogued as COSV55250435; called by muse, mutect2, varscan2
- RNF17 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55038451; called by muse, mutect2, varscan2
- ROBO1 | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV71393420; called by muse, mutect2, varscan2
- ROBO2 | c.549C>T p.I183= | Splice Region (SNP) | VAF 66/110 reads (60%) | catalogued as COSV59907147; called by muse, mutect2, varscan2
- ROBO2 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59907159; called by muse, mutect2, varscan2
- RORB | c.1189G>A p.E397K (on ENST00000396204 / NM_001365023.1; = p.E386K on NM_006914.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as rs775496473, COSV65335109; called by muse, mutect2, varscan2
- RP1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV55114825; called by muse, mutect2, varscan2
- RPH3A | c.680G>A p.G227E (on ENST00000389385 / NM_001143854.2; = p.G223E on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.843); catalogued as COSV66990739; called by muse, mutect2, varscan2
- RPH3AL | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV58740923; called by muse, mutect2, varscan2
- RPS6KA6 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53118648; called by muse, mutect2, varscan2
- RPTN | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 608/1133 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV60166331; called by mutect2, varscan2
- RSBN1L | c.1907T>C p.V636A | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58507737; called by muse, mutect2, varscan2
- RSPH1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV52318519; called by muse, mutect2, varscan2
- RSPO1 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62974091; called by muse, mutect2, varscan2
- RXRA | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.116); catalogued as COSV62684108; called by muse, mutect2, varscan2
- RXRB | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV63399656; called by muse, mutect2, varscan2
- RYR1 | c.8067G>A p.K2689= | Splice Region (SNP) | VAF 11/38 reads (29%) | catalogued as CS105863, COSV62094804; called by muse, mutect2, varscan2
- RYR2 | c.14464C>T p.R4822C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63679577; called by muse, mutect2, varscan2
- S100A2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64184693; called by muse, mutect2, varscan2
- S100A7A | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV61330364; called by muse, mutect2, varscan2
- SAMD9L | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs916258664, COSV59080881; called by muse, mutect2, varscan2
- SARDH | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64099275; called by muse, mutect2, varscan2
- SARDH | c.1151-1G>A p.X384_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as rs1342970131, COSV64104344; called by muse, mutect2, varscan2
- SASS6 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54927528; called by muse, mutect2, varscan2
- SCG3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1459980606, COSV55020862; called by muse, mutect2, varscan2
- SCML2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV52620355; called by muse, mutect2
- SCN10A | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs267599806, COSV71860999; called by muse, mutect2, varscan2
- SCN10A | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101479515, COSV71861001; called by muse, mutect2, varscan2
- SCN1A | c.4599G>A p.M1533I (on ENST00000303395 / NM_001202435.3; = p.M1522I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV57666998; called by muse, mutect2, varscan2
- SCN3A | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1318656039, COSV51807503; called by muse, mutect2, varscan2
- SCO1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV55135230; called by muse, mutect2, varscan2
- SCRIB | c.4568C>T p.S1523F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782160875, COSV57585472, COSV57588338; called by muse, mutect2
- SDK1 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs1364713936, COSV67357225; called by muse, mutect2, varscan2
- SDK2 | c.5548G>A p.G1850S | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66184646; called by muse, mutect2, varscan2
- SDR16C5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV58126151; called by muse, mutect2, varscan2
- SEMA3G | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as COSV51595151; called by muse, mutect2, varscan2
- SEMA5A | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs767167913, COSV66790213; called by muse, mutect2, varscan2
- SEMG1 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as COSV54874014; called by muse, mutect2, varscan2
- SERINC5 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72595971; called by muse, mutect2, varscan2
- SERPINB10 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV53072702; called by muse, mutect2, varscan2
- SERPINB2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100208439, COSV55091994; called by muse, mutect2, varscan2
- SERPINB3 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746000475, COSV52191031; called by muse, mutect2, varscan2
- SERPINB4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61984761; called by muse, mutect2, varscan2
- SERPINF2 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 110/200 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.285); catalogued as COSV60664122; called by muse, mutect2, varscan2
- SFSWAP | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV55521319; called by muse, mutect2, varscan2
- SH3RF2 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 86/142 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63038482; called by muse, mutect2, varscan2
- SH3TC2 | c.3395T>C p.L1132P | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60462537; called by muse, mutect2, varscan2
- SHISAL1 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV66987804; called by muse, mutect2, varscan2
- SHROOM2 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV66605871; called by muse, mutect2, varscan2
- SHROOM3 | c.2137G>A p.G713R | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770303497, COSV56027503, COSV56037182; called by muse, mutect2, varscan2
- SIGLEC14 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99707638; called by muse, mutect2, varscan2
- SIGLEC8 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750457526, COSV58473258; called by muse, mutect2, varscan2
- SIK3 | c.1135C>T p.R379* (on ENST00000445177 / NM_001366686.2; = p.R385* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/47 reads (74%) | catalogued as COSV52612717; called by muse, mutect2, varscan2
- SIN3A | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV64582546; called by muse, mutect2, varscan2
- SIRPG | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53806943; called by muse, mutect2, varscan2
- SLC12A8 | c.459T>G p.N153K | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV58865311; called by muse, mutect2, varscan2
- SLC12A9 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981273383, COSV51932634; called by muse, mutect2, varscan2
- SLC15A2 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs552479039, COSV55197294; called by muse, mutect2, varscan2
- SLC16A12 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV57949161; called by muse, mutect2, varscan2
- SLC27A2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51058432; called by muse, mutect2, varscan2
- SLC38A5 | c.243C>T p.F81= | Splice Region (SNP) | VAF 16/24 reads (67%) | catalogued as COSV58334018; called by muse, mutect2, varscan2
- SLC39A5 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs772831047, COSV57191411; called by muse, mutect2, varscan2
- SLC4A3 | c.2343C>T p.F781= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as COSV56092992; called by muse, mutect2, varscan2
- SLC4A7 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440075094, COSV55396375; called by muse, mutect2, varscan2
- SLC5A8 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV73310533; called by muse, mutect2, varscan2
- SLC5A8 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs773903392, COSV73310535; called by muse, mutect2, varscan2
- SLC6A1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55114504; called by muse, mutect2, varscan2
- SLC6A3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54362925; called by muse, mutect2, varscan2
- SLC6A4 | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.47); catalogued as rs774549180, COSV55566399; called by muse, mutect2, varscan2
- SLC8A3 | c.1919G>A p.R640K (on ENST00000381269 / NM_183002.3; = p.R638K on NM_033262.4) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV53688290; called by muse, mutect2, varscan2
- SLC8A3 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV63520273; called by muse, mutect2, varscan2
- SMC5 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63192533; called by muse, mutect2, varscan2
- SMOC1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV62760511; called by muse, mutect2, varscan2
- SMURF2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568303941, COSV52314549; called by muse, mutect2, varscan2
- SNCAIP | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs868328409, COSV54407948; called by muse, mutect2, varscan2
- SORCS2 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61167535; called by muse, mutect2, varscan2
- SORCS3 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs752889297, COSV100865595, COSV63807915; called by muse, mutect2, varscan2
- SPACA3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52191009; called by muse, mutect2, varscan2
- SPACA3 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370068963; called by muse, mutect2, varscan2
- SPAG17 | c.4199G>A p.G1400E | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60456929; called by muse, varscan2
- SPAG17 | c.4102C>T p.H1368Y | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV60455956; called by muse, varscan2
- SPANXB1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.956); catalogued as rs1218463614; called by muse, mutect2, varscan2
- SPATA22 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52152295; called by muse, mutect2, varscan2
- SPATA31D1 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.824); catalogued as COSV61194835, COSV61201105; called by muse, mutect2, varscan2
- SPEF2 | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV57428549; called by muse, mutect2, varscan2
- SPEF2 | c.4546C>T p.Q1516* | Nonsense Mutation (SNP) | VAF 29/164 reads (18%) | catalogued as COSV57428558, COSV57428799; called by muse, mutect2, varscan2
- SPEF2 | c.4961G>A p.G1654E | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57428581; called by muse, mutect2, varscan2
- SPEM1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs769857949, COSV57209855; called by muse, mutect2, varscan2
- SPG11 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.484); catalogued as rs1324881129, COSV55993564; called by muse, mutect2, varscan2
- SPTA1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs771256946, COSV63749895, COSV63751826; called by muse, mutect2, varscan2
- SPTB | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67631117; called by muse, mutect2
- SPTBN2 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs201646010, COSV59450510; called by muse, mutect2, varscan2
- SPTBN4 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as COSV58947506; called by muse, mutect2, varscan2
- SPZ1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV57062989; called by muse, mutect2, varscan2
- SRCAP | c.5051C>T p.A1684V | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.045); catalogued as COSV52671110; called by muse, mutect2, varscan2
- SS18 | c.1214C>T p.P405L (on ENST00000415083 / NM_001007559.3; = p.P374L on NM_005637.3) | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV52260614; called by muse, mutect2, varscan2
- ST8SIA3 | c.311T>G p.I104S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | PolyPhen possibly damaging (0.622); catalogued as COSV60653908; called by muse, mutect2, varscan2
- STAU1 | c.1267G>A p.E423K (on ENST00000371856 / NM_001319135.1; = p.E342K on NM_004602.3) | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV61458980; called by muse, mutect2, varscan2
- STC1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51688245; called by muse, mutect2, varscan2
- STK31 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as COSV63455496; called by muse, mutect2, varscan2
- STK31 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV63455504; called by muse, varscan2
- STMN1 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63481254; called by muse, mutect2, varscan2
- SULT1C3 | c.622-1G>A p.X208_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as rs1448183485, COSV100227407, COSV61252782; called by muse, mutect2, varscan2
- SVEP1 | c.7585C>T p.R2529W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs779073227, COSV52834974; called by muse, mutect2
- SVEP1 | c.7322C>T p.P2441L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52838245; called by muse, mutect2, varscan2
- SVEP1 | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1198650002, COSV52838252; called by muse, mutect2, varscan2
- SYCE1 | c.223G>A p.G75R (on ENST00000343131 / NM_001143764.3; = p.G39R on NM_130784.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); catalogued as COSV58216781; called by muse, mutect2, varscan2
- SYNDIG1 | c.559T>G p.F187V | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65234106; called by muse, mutect2, varscan2
- SYNE1 | c.3755C>T p.S1252F (on ENST00000367255 / NM_182961.4; = p.S1259F on NM_033071.3) | Missense Mutation (SNP) | VAF 57/73 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV54958715; called by muse, mutect2, varscan2
- SYNE2 | c.5503C>T p.H1835Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59947344; called by muse, mutect2, varscan2
- TAAR6 | c.950G>A p.W317* | Nonsense Mutation (SNP) | VAF 62/82 reads (76%) | catalogued as rs1562181187, COSV51583306, COSV99256857; called by muse, mutect2, varscan2
- TACC2 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as COSV57752989; called by muse, mutect2
- TANC1 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55086536; called by muse, mutect2, varscan2
- TBC1D13 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772793539, COSV56354058; called by muse, mutect2, varscan2
- TBX15 | c.1126C>T p.H376Y (on ENST00000369429 / NM_001330677.2; = p.H270Y on NM_152380.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV52870399; called by muse, mutect2, varscan2
- TCF25 | c.1039del p.L347Sfs*5 | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | catalogued as rs1380403194; called by mutect2, pindel*
- TDRD1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV52589791; called by muse, mutect2, varscan2
- TDRD5 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV54241548, COSV54244644; called by muse, mutect2, varscan2
- TEK | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66228591; called by muse, mutect2, varscan2
- TENM2 | c.1744G>A p.G582R (on ENST00000518659 / NM_001122679.2; = p.G350R on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101319172, COSV69127954; called by muse, mutect2, varscan2
- TENM3 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV101305564, COSV69305133; called by muse, mutect2, varscan2
- TENM4 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1193400951, COSV53609556; called by muse, mutect2, varscan2
- TET2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV54406983, COSV54415717, COSV54427060; called by muse, mutect2, varscan2
- TEX14 | c.2378C>T p.A793V (on ENST00000240361 / NM_001201457.2; = p.A787V on NM_031272.5) | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53615049; called by muse, mutect2, varscan2
- TF | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53919072, COSV53919656; called by muse, mutect2, varscan2
- TFR2 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV56153878; called by muse, mutect2, varscan2
- THEMIS | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV64069310; called by muse, mutect2, varscan2
- THRA | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.374); catalogued as COSV52842211; called by muse, mutect2, varscan2
- THSD7B | c.3538G>A p.E1180K (on ENST00000272643; = p.E1178K on NM_001316349.2) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.699); catalogued as COSV55655747, COSV99742785; called by muse, mutect2, varscan2
- TIFAB | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs778048077, COSV72345772; called by muse, mutect2, varscan2
- TLE2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53579502; called by muse, mutect2
- TLR4 | c.1606G>A p.D536N (on ENST00000355622 / NM_138554.5; = p.D496N on NM_003266.4) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as rs1184583373, COSV62923009; called by muse, mutect2, varscan2
- TLR5 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV60558661; called by muse, mutect2, varscan2
- TLR5 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV60558699, COSV60559507; called by muse, mutect2, varscan2
- TMEM132B | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV54751124, COSV54758150; called by muse, mutect2, varscan2
- TMEM151A | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs753015947, COSV59173522; called by muse, mutect2, varscan2
- TMEM176B | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1169726424, COSV58439328; called by muse, mutect2, varscan2
- TMEM98 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55582564; called by muse, mutect2, varscan2
- TMPRSS3 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.101); catalogued as COSV52304628; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59528498; called by muse, mutect2, varscan2
- TNN | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1304938837, COSV53424859; called by muse, mutect2, varscan2
- TNN | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778789960, COSV53424869; called by muse, mutect2, varscan2
- TNRC6B | c.2166G>A p.W722* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV57293514; called by muse, mutect2, varscan2
- TNRC6B | c.4717C>T p.P1573S (on ENST00000454349 / NM_001162501.2; = p.P1463S on NM_015088.3) | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); catalogued as COSV57293523; called by muse, mutect2, varscan2
- TNXB | c.12221C>T p.S4074L (on ENST00000647633; = p.S3827L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1008389232, COSV64477509; called by muse, mutect2, varscan2
- TNXB | c.9818G>A p.G3273E (on ENST00000647633; = p.G3026E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV64477533; called by muse, mutect2, varscan2
- TOX3 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV54865671; called by muse, mutect2, varscan2
- TPRA1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56160541; called by muse, mutect2, varscan2
- TPRG1 | c.303G>A p.K101= | Splice Region (SNP) | VAF 40/103 reads (39%) | catalogued as COSV61464582; called by muse, mutect2, varscan2
- TRAV1-1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs757819358; called by muse, mutect2, varscan2
- TRAV8-7 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs926834544; called by muse, mutect2, varscan2
- TRIM55 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs758591514, COSV52545441, COSV99396906; called by muse, mutect2, varscan2
- TRIM58 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370498805; called by muse, mutect2, varscan2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TRIML2 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58715615; called by muse, mutect2, varscan2
- TRIOBP | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs763229296, COSV60376266, COSV60380444; called by muse, mutect2, varscan2
- TRPA1 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV51555777, COSV51559719; called by muse, mutect2, varscan2
- TRPM8 | c.1245C>T p.A415= | Splice Region (SNP) | VAF 16/64 reads (25%) | catalogued as COSV61221698; called by muse, mutect2, varscan2
- TRPV5 | c.587-1G>A p.X196_splice | Splice Site (SNP) | VAF 42/103 reads (41%) | catalogued as COSV54684860; called by muse, mutect2, varscan2
- TSC2 | c.1842C>T p.A614= | Splice Region (SNP) | VAF 20/33 reads (61%) | catalogued as rs201575136, COSV54762021; called by muse, mutect2, varscan2
- TSHZ2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV61588247; called by muse, mutect2, varscan2
- TTC3 | c.5867C>T p.S1956F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV61289297; called by muse, mutect2, varscan2
- TTN | c.63919C>T p.L21307F (on ENST00000591111; = p.L13883F on NM_003319.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | PolyPhen possibly damaging (0.73); catalogued as COSV59995020; called by muse, mutect2, varscan2
- TTN | c.12170G>A p.G4057E (on ENST00000591111; = p.G4011E on NM_003319.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV60169984; called by muse, mutect2, varscan2
- TUBA8 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs748797090, COSV57812825; called by muse, mutect2, varscan2
- TUBGCP2 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV53304647; called by muse, mutect2
- TWNK | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52967516; called by muse, mutect2, varscan2
- UCHL5 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV66486154; called by muse, mutect2, varscan2
- UGT2B17 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV58500750; called by muse, mutect2, varscan2
- UGT3A1 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57097349; called by muse, mutect2, varscan2
- UGT3A2 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV104390753, COSV56929953; called by muse, mutect2, varscan2
- UNC13C | c.5832G>A p.M1944I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1280810605, COSV52863697; called by muse, mutect2, varscan2
- UNC79 | c.2388G>A p.M796I (on ENST00000393151 / NM_001346218.2; = p.M619I on NM_020818.5) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs1267848033, COSV56382650; called by muse, mutect2, varscan2
- USF3 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.825); catalogued as rs770218667, COSV57071735; called by muse, mutect2, varscan2
- USP32 | c.4547C>T p.S1516L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV56264945; called by muse, mutect2, varscan2
- USPL1 | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54999572; called by muse, mutect2, varscan2
- UTS2 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 50/79 reads (63%) | catalogued as COSV50013242; called by muse, mutect2, varscan2
- UVSSA | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV66229448; called by muse, mutect2, varscan2
- VAV3 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58378863; called by muse, mutect2, varscan2
- VPS39 | c.1408C>T p.H470Y (on ENST00000348544 / NM_001301138.2; = p.H459Y on NM_015289.5) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV58788996; called by muse, mutect2, varscan2
- WASHC2A | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99254697; called by muse, mutect2, varscan2
- WDPCP | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV55414170; called by mutect2, varscan2
- WDR11 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV54787551; called by muse, mutect2, varscan2
- WDR25 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs200027763; called by muse, mutect2, varscan2
- WDR49 | c.1730C>T p.S577L (on ENST00000308378 / NM_001366158.1; = p.S918L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV100393157; called by muse, mutect2, varscan2
- WDR49 | c.1634C>T p.S545F (on ENST00000308378 / NM_001366158.1; = p.S886F on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV57706545, COSV57711317; called by muse, mutect2, varscan2
- WDR49 | c.910G>A p.G304R (on ENST00000308378 / NM_001366158.1; = p.G645R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57706557; called by muse, mutect2, varscan2
- WDR91 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV60369415; called by muse, mutect2, varscan2
- WDTC1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 85/174 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs267598533, COSV100089137; called by muse, mutect2, varscan2
- WNK2 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs1482672086, COSV52938730; called by muse, mutect2, varscan2
- WRN | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV53298987; called by muse, mutect2, varscan2
- XPO4 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV55006490, COSV55014131; called by muse, mutect2, varscan2
- YEATS2 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59364414; called by muse, mutect2, varscan2
- ZBED9 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1359504265, COSV71729335; called by muse, mutect2, varscan2
- ZBED9 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.956); catalogued as COSV71729336; called by muse, mutect2, varscan2
- ZC3H14 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs772979062, COSV51768548; called by muse, mutect2, varscan2
- ZC3H4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757941010, COSV99452479; called by muse, varscan2
502 further variants in this file (40 protein-altering or splice-affecting, 420 silent, 42 other) are not listed here.
